Gene-level copy-number profile of tumor specimen ALCH-AEOD-TTP1-A from ALCHEMIST case ALCH-AEOD, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 64.3 years (23,474 days).
Specimen ALCH-AEOD-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 61417915-54d5-4788-995a-10fab99b538e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AEOD-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,750 have no estimate.
https://portal.gdc.cancer.gov/files/fc671b01-f1e0-4cbb-b023-2dd6b0cd35a2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 20; copy number 1: 6,628; copy number 2: 47,428; copy number 3: 4,494; copy number 4: 285; copy number 5: 10; copy number 6: 8.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:39,451,045–39,522,852, 1 gene: ADAM3A.
- chr9:39,355,669–39,508,885, 7 genes: SPATA31A1, BX005214.3, FAM74A1, BX005214.1, BX005214.2, ZNF658B, SKP1P3.
- chr9:39,886,861–39,892,895, 3 genes: RN7SL763P, SNORA70, CR769767.1.
- chr9:39,983,821–39,984,401, 1 gene: RPL7AP49.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 18 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:248,548,756–248,601,869, 7 genes, copy number 5 (within-gene range 5–11): AC098483.1, OR2AS1P, OR2T29, OR2T34, OR2T10, Y_RNA, AC098483.2.
- chr5:158,225,352–159,099,916, 8 genes, copy number 6 (within-gene range 4–6): AC025437.3, AC025437.2, AC025437.1, LINC02227, AC091979.1, AC091979.2, AC091939.1, EBF1.
- chr5:159,448,556–159,466,291, 1 gene, copy number 5: LINC01845.
- chr8:43,672,823–43,674,591, 2 genes, copy number 5: AC139365.2, AC139365.1.

Autosomal genes at a single copy (total copy number 1): 5,901. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
